Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A8GM, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A8GM-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) LEFT SHOULDER, SKIN PUNCH:

Please see addendum report with examination of additional levels.

(B) LEFT NECK DISSECTION, LEVELS II-V:

Level II: MESTASTATIC MELANOMA IN SOFT TISSUE AND MATTED LYMPH NODES.

TUMOR SIZE 50.0 X 35.0 MM GROSSLY.

EXTRACAPSULAR EXTENSION PRESENT.

Eleven lymph nodes, negative for metastatic melanoma. (0/11)

Incidental neural tumor with features of traumatic neuroma.

Level III: Thirteen lymph nodes, negative for metastatic melanoma. (0/13)

Level IV: Three lymph nodes, negative for metastatic melanoma. (0/3)

Level V: Ten lymph nodes, negative for metastatic melanoma. (0/10)

Entire report and diagnosis completed by

ICD-O-3
Melanoma NOS 8720/3
Site: lymph nodes head, face
& neck C77.0
JW 11/27/13

GROSS DESCRIPTION

(A) LEFT SHOULDER NEVUS - A tan-pink punch of skin (0.8 x 0.6 x 0.6 cm). The skin surface is remarkable for a centrally located pigmented area (0.3 cm). The specimen is inked blue and bisected. Toto in A.

(B) LEFT NECK DISSECTION, LEVEL II-V - A tan-pink irregular tissue fragment (13.0 x 8.0 x 1.5 cm). The specimen is oriented by the surgeon as follows:

Level II (8.0 x 4.0 x 1.0 cm). Dissection reveals 13 possible lymph nodes ranging from 0.1 x 0.1 x 0.1 cm to 5.0 x 3.5 x 2.5 cm. Tissue from the largest possible matted lymph node is submitted to tissue bank.

SECTION CODE: B1, five lymph nodes; B2, four lymph nodes; B3, three lymph nodes; B4-B7, largest lymph node.

Level III - A tan-pink irregular tissue fragment (6.0 x 5.5 x 1.3 cm). Dissection reveals 12 lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 1.3 x 1.0 x 0.5 cm.

SECTION CODE: B8, five lymph nodes; B9, four lymph nodes; B10, two lymph nodes; B11, one lymph node trisected.

Level IV - A tan-pink irregular tissue fragment (4.0 x 3.0 x 1.5 cm). Dissection reveals three lymph nodes ranging from 0.2 x 0.1 x 0.1 cm to 1.5 x 1.0 x 0.8 cm.

SECTION CODE: B12, two lymph nodes; B13, one lymph node serially sectioned.

Level V - A tan-pink irregular tissue fragment (6.5 x 4.5 x 2.0 cm). Dissection reveals 12 lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 1.5 x 1.0 x 0.8 cm.

SECTION CODE: B14, five lymph nodes; B15, four lymph nodes; B16, two lymph nodes; B17, one lymph node trisected.

CLINICAL HISTORY

Melanoma, left neck.

SNOMED CODES

T-02410, T-C4800, M-87206, M-72750, M-78770

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

. These tests have not been

Released by:

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

Addendum completed by

DIAGNOSIS

This addendum is issued to report additional findings.

For specimen A, additional level sections are examined and reveal a seborrheic keratosis, free of tissue edges.

SNOMED CODES

M-72750
Released by:

-----END OF REPORT-----

Criteria	lw 10/28/13	Yes	No
clPAA Discrepancy			✓

Source: NCI Genomic Data Commons file 1efef693-8a5e-44ea-97a2-d17448e711b8 (TCGA-D3-A8GM.38FCA07B-7313-438C-BE20-4C370BAAFC66.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).